Somatic mutation profile of tumor specimen MP2PRT-PANWPU-TMP1-A (aliquot MP2PRT-PANWPU-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANWPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,519 days).
Specimen MP2PRT-PANWPU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf8d8460-f756-42ee-8cd7-542588bc7f58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWPU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWPU-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71dc6406-e083-4b7e-8af5-f0c9783dcdb5

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC1 | c.1672T>C p.S558P | Missense Mutation (SNP) | VAF 47/450 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs1419354531; called by muse, mutect2, varscan2
- NBAS | c.5416G>A p.E1806K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs772499559; called by muse, mutect2
- SALL3 | c.1138A>G p.I380V | Missense Mutation (SNP) | VAF 34/856 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as rs780061115; called by muse, mutect2
- DNAH5 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- GALK2 | c.1264G>C p.A422P | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2
